Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A28W, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A28W-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Right thyroid nodule.

PROCEDURE: Thyroidectomy total.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

Collection Date:

FINAL DIAGNOSIS:**PART 1: THYROID, TOTAL THYROIDECTOMY (45 GRAMS) -**

- A. PAPILLARY THYROID CARCINOMA, TWO FOCI, LEFT AND RIGHT.
- B. LARGEST FOCUS: RIGHT (3.0 CM), WELL DEMARCATED, FOLLICULAR PATTERN PREDOMINANT (see comment).
- C. LEFT FOCUS: TALL CELL VARIANT (0.8 CM).
- D. ALL FOCI CONFINED TO THYROID; NO ANGIOLYMPHATIC INVASION.
- E. ONE REACTIVE LYMPH NODE, NO TUMOR PRESENT (0/1).
- F. PATHOLOGIC STAGE: pT2 N0
- G. CHRONIC LYMPHOCYTIC THYROIDITIS.

**PART 2: LYMPH NODES, CENTRAL COMPARTMENT, SELECTIVE DISSECTION -
THREE LYMPH NODES, NO TUMOR PRESENT (0/3).****COMMENT:**

Select slides were reviewed with Dr. [REDACTED] who agree that the larger nodule contains papillary carcinoma. Given the focality of the diagnostic nuclear features in the larger nodule, it is possible that the carcinoma is arising within a follicular adenoma.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Right Lobe, Left Lobe
TUMOR FOCALITY: Multifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 3 cm
HISTOLOGIC TYPE*: Papillary carcinoma
TNM DESCRIPTORS: m
PRIMARY TUMOR (pT): pT2
REGIONAL LYMPH NODES (pN): pN0

Number of regional lymph nodes examined: 4
Number of regional lymph nodes involved: 0

EXTRANODAL EXTENSION: Not identified
DISTANT METASTASIS (pM): Not applicable
EXTRATHYROIDAL EXTENSION: Not identified
MARGINS: Margins uninvolved by carcinoma
LYMPH-VASCULAR INVASION: Not identified

ADDITIONAL PATHOLOGIC FINDINGS: Other: chronic lymphocytic thyroiditis

ICD-0-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, nos C73.9

for
5/25/11

Case is (include):	DISQUALIFIED	

Source: NCI Genomic Data Commons file 2e13658d-378a-4171-b9a7-d559d0c012d7 (TCGA-BJ-A28W.098C0E08-B4E1-4EE1-8472-0A737A8C521E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).